Somatic mutation profile of tumor specimen ALCH-ADRQ-TTP1-A (aliquot ALCH-ADRQ-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADRQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,358 days).
Specimen ALCH-ADRQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d176b835-22db-46e4-8a01-78158cb86996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADRQ-NB1-A (Blood Derived Normal), aliquot ALCH-ADRQ-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f35ffb73-96e8-4784-863c-dda2b04ecc56

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 4, Intron 4, RNA 3, Splice Site 2, 5'UTR 1, In Frame Del 1, Frame Shift Del 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 56/327 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 145/1076 reads (13%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- ACP6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978886014, COSV65076275; called by muse, mutect2
- BRS3 | c.787-1G>C p.X263_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | catalogued as COSV65710978; called by mutect2, varscan2
- CDH8 | c.1772C>T p.T591I | Missense Mutation (SNP) | VAF 36/1463 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54867838; called by muse, mutect2
- CIZ1 | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.352); catalogued as COSV52971012; called by muse, mutect2, varscan2
- CNTN5 | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 82/1013 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1179336255; called by muse, mutect2
- DLG2 | c.2538A>G p.I846M | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1252476217; called by muse, mutect2
- EGFR | c.2302A>T p.S768C | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51769243; called by muse, mutect2, varscan2
- HTRA1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 39/995 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs864622781, CM157924, COSV64565016; called by muse, mutect2
- NLRP9 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60459475; called by muse, mutect2
- PCDHB5 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 50/804 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV50657019; called by muse, mutect2
- PKD1L3 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 37/229 reads (16%) | catalogued as COSV100626287; called by muse, mutect2, varscan2
- PSD4 | c.2482G>T p.G828W | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs780617813; called by mutect2, varscan2
- TRIOBP | c.5078C>T p.A1693V | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs757126892; called by muse, mutect2
- ZNF442 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.786); catalogued as rs1187107808; called by muse, mutect2
- ARHGAP10 | c.2272+2T>C p.X758_splice | Splice Site (SNP) | VAF 42/368 reads (11%) | called by muse, mutect2, varscan2
- ASMTL | c.486A>T p.E162D | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATM | c.8723_8725del p.F2908_R2909delins* | Nonsense Mutation (DEL) | VAF 96/545 reads (18%) | called by mutect2, pindel, varscan2
- BNC2 | c.1119del p.T374Hfs*14 | Frame Shift Del (DEL) | VAF 67/635 reads (11%) | called by mutect2, pindel, varscan2
- C5orf34 | c.1386A>C p.R462S | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CACHD1 | c.3808G>T p.V1270F | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CCDC168 | c.8993C>G p.S2998* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- FBXO30 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG | c.3728G>A p.W1243* | Nonsense Mutation (SNP) | VAF 42/861 reads (5%) | called by muse, mutect2
- FLG | c.3446C>A p.A1149E | Missense Mutation (SNP) | VAF 42/986 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.206); called by muse, mutect2
- GGH | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTP1 | c.430A>T p.I144F | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- INPP5E | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBEA | c.6996G>T p.L2332F | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NBEA | c.6997G>T p.D2333Y | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NDUFA6 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 34/910 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2
- PLK1 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STYXL2 | c.1233G>C p.W411C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- TTN | c.15608A>G p.Y5203C (on ENST00000591111; = p.Y4276C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/190 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF692 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 84/1018 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- ZXDA | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2
- ALPK2 | c.4839T>C p.S1613= | Silent (SNP) | VAF 28/328 reads (9%) | called by muse, mutect2
- FAM166A | c.117G>A p.T39= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs368787356, COSV100458240, COSV61116926, COSV61117381; called by muse, mutect2, varscan2
- GREB1 | c.3588G>A p.P1196= | Silent (SNP) | VAF 34/311 reads (11%) | catalogued as rs772502940, COSV52182037; called by muse, mutect2, varscan2
- SNX18 | c.909G>A p.T303= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100410358, COSV57989357; called by muse, mutect2
- SPECC1L | c.906C>T p.N302= | Silent (SNP) | VAF 76/869 reads (9%) | called by muse, mutect2
- USH2A | c.3801G>A p.A1267= | Silent (SNP) | VAF 34/516 reads (7%) | catalogued as rs537863698, COSV100231306, COSV56451059; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- ZNF208 | c.3411A>T p.G1137= | Silent (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- AC004951.3 | n.708G>A | RNA (SNP) | VAF 19/470 reads (4%) | called by muse, mutect2
- ARHGEF25 | chr12:57619772 G>T | 3'Flank (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- COMMD8 | c.-3G>A | 5'UTR (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- IKZF1 | c.161-8331T>A | Intron (SNP) | VAF 32/295 reads (11%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1582C>T | RNA (SNP) | VAF 56/465 reads (12%) | catalogued as rs1393156529; called by muse, mutect2
- PLXDC1 | c.*4357del | 3'UTR (DEL) | VAF 51/465 reads (11%) | called by mutect2, pindel*
- PSME2 | c.498-13T>C | Intron (SNP) | VAF 53/349 reads (15%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6251A>C | Intron (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- SNX6 | c.42+17G>T | Intron (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.581C>T | RNA (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2
